Somatic mutation profile of tumor specimen TCGA-CV-7430-01A (aliquot TCGA-CV-7430-01A-11D-2129-08) from TCGA case TCGA-CV-7430, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 56.8 years (20,763 days).
Specimen TCGA-CV-7430-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c994171d-783b-487c-bda1-e23e396cf9a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7430-10A (Blood Derived Normal), aliquot TCGA-CV-7430-10A-01D-2129-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e57d4ee4-2a5c-4500-8b14-84fcbcdc446d

The open-access MAF lists 120 somatic variants for this specimen: 94 protein-altering or splice-affecting, 24 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Silent 24, Nonsense Mutation 5, Frame Shift Del 4, Splice Site 3, In Frame Del 1, Intron 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RRAS2 | c.215A>T p.Q72L | Missense Mutation (SNP) | VAF 38/77 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs113954997, COSV56329169; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.377A>G p.Y126C | Missense Mutation (SNP) | VAF 22/34 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555526335, CM115636, COSV52689293, COSV52760406, COSV52970718; ClinVar: uncertain significance / likely pathogenic; called by muse, varscan2
- ADM2 | c.287C>T p.S96L | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs549309630, COSV53313520; called by muse, mutect2, varscan2
- AGBL5 | c.483C>A p.Y161* | Nonsense Mutation (SNP) | VAF 91/240 reads (38%) | catalogued as COSV100549092; called by muse, mutect2, varscan2
- AGL | c.3154A>G p.K1052E | Missense Mutation (SNP) | VAF 57/115 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.082); catalogued as COSV99649175; called by muse, mutect2, varscan2
- ALDH1L1 | c.1079T>A p.L360Q | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV99856799; called by muse, mutect2, varscan2
- ALPK2 | c.2263G>A p.V755M | Missense Mutation (SNP) | VAF 6/137 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.258); catalogued as COSV100864351; called by muse, mutect2
- ANK2 | c.7249G>A p.D2417N | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.747); catalogued as COSV52180816; called by muse, mutect2, varscan2
- APLF | c.1264C>G p.P422A | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100376704; called by muse, mutect2, varscan2
- ARID1A | c.2591G>T p.G864V | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100251620; called by muse, mutect2, varscan2
- BARHL2 | c.1007C>T p.A336V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.438); catalogued as COSV99059756; called by muse, mutect2, varscan2
- BRCA2 | c.9945A>T p.K3315N | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.892); catalogued as COSV101200888; called by muse, mutect2, varscan2
- CD1A | c.731A>T p.Q244L | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.226); catalogued as COSV99192353; called by muse, varscan2
- CDR2L | c.461C>T p.T154I | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs1038900377, COSV100464576; called by muse, mutect2
- CHST14 | c.538C>A p.L180I | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as COSV100086953; called by muse, mutect2, varscan2
- CLDND1 | c.148A>T p.I50F | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV100360719; called by muse, mutect2, varscan2
- CLEC16A | c.1141C>T p.H381Y | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.133); catalogued as COSV101278007; called by muse, mutect2, varscan2
- CNKSR2 | c.741+1G>A p.X247_splice | Splice Site (SNP) | VAF 16/25 reads (64%) | catalogued as COSV99668452; called by muse, mutect2, varscan2
- COL14A1 | c.1636G>A p.V546I | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.017); catalogued as COSV99919222; called by muse, mutect2, varscan2
- DLG2 | c.269G>A p.C90Y (on ENST00000650630 / NM_001351274.2; = p.C53Y on NM_001142699.3) | Missense Mutation (SNP) | VAF 45/167 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.138); catalogued as COSV65874541; called by muse, mutect2, varscan2
- DNAH5 | c.3386C>A p.S1129Y | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.614); catalogued as COSV54251925, COSV99449543; called by muse, mutect2, varscan2
- ECPAS | c.2286A>C p.K762N | Missense Mutation (SNP) | VAF 207/398 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV99398233; called by muse, mutect2, varscan2
- FAF2 | c.244G>A p.V82I | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV99990451; called by muse, mutect2, varscan2
- FAM135B | c.265T>C p.F89L | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99357102; called by muse, mutect2, varscan2
- FAM160B1 | c.62C>G p.P21R | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); catalogued as COSV100985154; called by muse, mutect2, varscan2
- FBXO31 | c.721G>T p.G241W | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100291405; called by muse, mutect2, varscan2
- FER1L5 | c.3983C>T p.P1328L (on ENST00000623019; = p.P1301L on NM_001293083.2) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs781440844, COSV101208864; called by muse, varscan2
- FNDC1 | c.3695C>A p.P1232H | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as COSV99795767; called by muse, mutect2
- GLIS3 | c.1192A>G p.K398E | Missense Mutation (SNP) | VAF 73/108 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100173953; called by muse, mutect2, varscan2
- IGHG4 | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 40/240 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as rs374177525; called by muse, mutect2
- IGHG4 | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.951); catalogued as rs777067694; called by muse, mutect2, varscan2
- IQCG | c.1034T>C p.L345P | Missense Mutation (SNP) | VAF 105/759 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54564138, COSV99502309; called by muse, mutect2, varscan2
- ITGB3 | c.1259C>T p.T420M | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.692); catalogued as rs147758772; called by muse, mutect2, varscan2
- JRK | c.1542G>T p.Q514H | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV101401091; called by muse, mutect2, varscan2
- KCNJ8 | c.1066C>T p.R356* | Nonsense Mutation (SNP) | VAF 76/235 reads (32%) | catalogued as COSV99557552; called by muse, mutect2, varscan2
- KCNJ9 | c.328G>C p.A110P | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100927745; called by muse, mutect2, varscan2
- KCNU1 | c.2219C>G p.A740G | Missense Mutation (SNP) | VAF 113/370 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV101299189; called by muse, mutect2, varscan2
- KMT2D | c.15121G>A p.G5041R | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99981461; called by muse, mutect2, varscan2
- KTN1 | c.3778G>C p.A1260P (on ENST00000395314 / NM_001271014.2; = p.A1203P on NM_004986.4) | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV100618326, COSV58540371; called by muse, mutect2, varscan2
- LILRA4 | c.44T>C p.L15P | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as COSV99393098; called by muse, mutect2, varscan2
- LIMK1 | c.1508G>A p.R503H | Missense Mutation (SNP) | VAF 4/92 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs782777225; called by muse, mutect2
- LIPC | c.344T>C p.V115A | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.55); PolyPhen benign (0.039); catalogued as COSV100134552; called by muse, mutect2, varscan2
- LRRC10 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100825480; called by muse, mutect2, varscan2
- MAST1 | c.1368C>T p.G456= | Splice Region (SNP) | VAF 22/68 reads (32%) | catalogued as rs768563655, COSV99262880; called by muse, mutect2, varscan2
- MCAM | c.1805C>T p.P602L | Missense Mutation (SNP) | VAF 67/175 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs528808258, COSV99876248; called by muse, mutect2, varscan2
- MRPS2 | c.416A>T p.K139M | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as COSV54094045, COSV99613446; called by muse, mutect2, varscan2
- MTHFD1L | c.2120T>A p.F707Y | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0.093); catalogued as COSV100945069; called by muse, varscan2
- MYH4 | c.348+1G>T p.X116_splice | Splice Site (SNP) | VAF 58/165 reads (35%) | catalogued as COSV55127327, COSV99701229; called by muse, mutect2, varscan2
- MYH7 | c.3569C>T p.A1190V | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.85); catalogued as rs1444900556, COSV62518973; called by muse, mutect2, varscan2
- NAV3 | c.240C>A p.S80R | Missense Mutation (SNP) | VAF 66/92 reads (72%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as rs1417154340, COSV57088099, COSV99890605; called by muse, mutect2, varscan2
- NRDE2 | c.1442G>A p.R481Q | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs150270537; called by muse, varscan2
- NT5DC2 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100194981; called by muse, mutect2
- NXF3 | c.837T>G p.C279W | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101221942; called by muse, mutect2
- OLFML2A | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.298); catalogued as rs779136629, COSV100053704; called by muse, varscan2
- OLFML2A | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 50/75 reads (67%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs1347996157, COSV99992568; called by muse, mutect2, varscan2
- OR2T12 | c.408G>A p.W136* | Nonsense Mutation (SNP) | VAF 27/80 reads (34%) | catalogued as COSV100527760; called by muse, mutect2, varscan2
- PAFAH2 | c.842A>C p.N281T | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100959261; called by muse, mutect2, varscan2
- PAPPA | c.2970C>A p.C990* | Nonsense Mutation (SNP) | VAF 23/86 reads (27%) | catalogued as COSV100074020, COSV60292564; called by muse, mutect2, varscan2
- PCDHB2 | c.676G>T p.G226C | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782163761, COSV99523143; called by muse, mutect2, varscan2
- PCDHB2 | c.677G>A p.G226D | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs949003962, COSV99523144; called by muse, mutect2, varscan2
- PCDHGA4 | c.926C>A p.T309K | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.935); catalogued as COSV53916393, COSV99537844; called by mutect2, varscan2
- PCED1B | c.1100T>C p.F367S | Missense Mutation (SNP) | VAF 61/238 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); catalogued as COSV101423639; called by muse, mutect2, varscan2
- PEX5L | c.675C>G p.S225R | Missense Mutation (SNP) | VAF 48/238 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.127); catalogued as COSV99828654; called by muse, mutect2, varscan2
- PHACTR3 | c.1024G>C p.A342P | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100732551; called by muse, mutect2, varscan2
- RAG2 | c.1524A>T p.K508N | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); catalogued as COSV100271291, COSV57558940; called by muse, mutect2
- RASA3 | c.2173G>C p.D725H | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100480509; called by muse, mutect2, varscan2
- RECQL | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.459); catalogued as COSV101389003; called by muse, mutect2, varscan2
- RNF24 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 59/153 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100270916; called by muse, mutect2, varscan2
- ROBO4 | c.2315C>A p.P772Q | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.606); catalogued as COSV100127579; called by muse, mutect2, varscan2
- RYR2 | c.13300G>C p.E4434Q | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.46); catalogued as COSV100770021; called by muse, mutect2, varscan2
- SCAI | c.1682G>A p.R561Q (on ENST00000336505 / NM_001144877.3; = p.R584Q on NM_173690.5) | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.614); catalogued as COSV100332541; called by muse, mutect2, varscan2
- SEMA5A | c.902A>G p.D301G | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.923); catalogued as COSV101228164; called by muse, mutect2, varscan2
- SERPINI1 | c.902T>A p.I301N | Missense Mutation (SNP) | VAF 73/310 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99855063; called by muse, mutect2, varscan2
- SF3B3 | c.1832A>T p.D611V | Missense Mutation (SNP) | VAF 65/236 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100209843; called by muse, mutect2, varscan2
- SI | c.3147C>A p.N1049K | Missense Mutation (SNP) | VAF 432/721 reads (60%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.521); catalogued as COSV100015461; called by muse, mutect2, varscan2
- SKIL | c.1319A>G p.K440R | Missense Mutation (SNP) | VAF 55/496 reads (11%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.629); catalogued as COSV99378249; called by muse, mutect2, varscan2
- SLC7A2 | c.749T>C p.M250T (on ENST00000494857 / NM_001370338.1; = p.M290T on NM_003046.6) | Missense Mutation (SNP) | VAF 33/46 reads (72%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.836); catalogued as COSV99134883; called by muse, mutect2, varscan2
- SLC8A3 | c.1288T>A p.Y430N | Missense Mutation (SNP) | VAF 75/181 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.393); catalogued as COSV100776180; called by muse, mutect2, varscan2
- SLCO5A1 | c.1192A>G p.K398E | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV99479970; called by muse, mutect2, varscan2
- SLF2 | c.1550A>G p.E517G | Missense Mutation (SNP) | VAF 73/165 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.367); catalogued as COSV99489150; called by muse, mutect2, varscan2
- SUGT1 | c.320A>G p.K107R | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.038); catalogued as COSV100139482; called by muse, mutect2, varscan2
- TIAM2 | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); catalogued as rs770893650, COSV100018979; called by muse, mutect2, varscan2
- TIGD4 | c.486G>A p.W162* | Nonsense Mutation (SNP) | VAF 36/66 reads (55%) | catalogued as COSV100427961; called by muse, mutect2, varscan2
- TTN | c.41753G>C p.R13918T (on ENST00000591111; = p.R6494T on NM_003319.4) | Missense Mutation (SNP) | VAF 46/125 reads (37%) | PolyPhen benign (0.265); catalogued as COSV100611700, COSV100611783; called by muse, mutect2, varscan2
- ZC3H18 | c.1668-1G>A p.X556_splice | Splice Site (SNP) | VAF 28/50 reads (56%) | catalogued as COSV99964103; called by muse, mutect2
- ZNF214 | c.1595G>A p.G532E | Missense Mutation (SNP) | VAF 60/105 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99547386; called by muse, mutect2, varscan2
- ZNF285 | c.1615C>G p.P539A | Missense Mutation (SNP) | VAF 42/73 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100449988; called by muse, mutect2, varscan2
- ZNF484 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 35/161 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100214643, COSV60258395; called by muse, mutect2, varscan2
- ZNF791 | c.142del p.E48Kfs*16 | Frame Shift Del (DEL) | VAF 24/46 reads (52%) | catalogued as COSV100589030; called by mutect2, pindel, varscan2
- ZNF804B | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT tolerated (0.79); PolyPhen benign (0.012); catalogued as rs139327261; called by muse, mutect2, varscan2
- CALB2 | c.810del p.M271Cfs*60 | Frame Shift Del (DEL) | VAF 48/187 reads (26%) | called by mutect2, pindel, varscan2
- JTB | c.336_338del p.V114del | In Frame Del (DEL) | VAF 45/127 reads (35%) | called by mutect2, pindel*, varscan2*
- LTBP1 | c.4725_4744del p.Q1575Hfs*14 (on ENST00000404816 / NM_206943.4; = p.Q1249Hfs*14 on NM_000627.4) | Frame Shift Del (DEL) | VAF 31/132 reads (23%) | called by mutect2, pindel, varscan2
- UGT2B7 | c.48_54del p.F16Lfs*20 | Frame Shift Del (DEL) | VAF 108/295 reads (37%) | called by mutect2, pindel, varscan2
- CDH3 | c.2190C>T p.L730= | Silent (SNP) | VAF 54/114 reads (47%) | catalogued as COSV99868295; called by muse, mutect2, varscan2
- CDH8 | c.729T>A p.V243= | Silent (SNP) | VAF 33/124 reads (27%) | catalogued as COSV100181422; called by muse, mutect2, varscan2
- CLCA2 | c.1836A>G p.E612= | Silent (SNP) | VAF 66/176 reads (38%) | catalogued as COSV100991530; called by muse, mutect2, varscan2
- CNTNAP4 | c.2463T>C p.F821= | Silent (SNP) | VAF 84/347 reads (24%) | catalogued as COSV100271313, COSV56683929; called by muse, mutect2, varscan2
- DSCAM | c.1818A>G p.R606= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV101260059; called by muse, mutect2, varscan2
- EVPL | c.378G>A p.V126= | Silent (SNP) | VAF 38/98 reads (39%) | catalogued as COSV100044473; called by muse, mutect2, varscan2
- IGBP1P2 | c.372C>A p.A124= | Silent (SNP) | VAF 27/82 reads (33%) | called by muse, mutect2, varscan2
- IGHMBP2 | c.1152C>T p.S384= | Silent (SNP) | VAF 45/147 reads (31%) | catalogued as COSV99662069; called by muse, mutect2, varscan2
- KCNJ2 | c.630G>A p.L210= | Silent (SNP) | VAF 30/95 reads (32%) | catalogued as COSV99696360; called by muse, mutect2, varscan2
- LINGO4 | c.402G>A p.L134= | Silent (SNP) | VAF 88/185 reads (48%) | catalogued as COSV100561937, COSV59091714; called by muse, mutect2, varscan2
- LRRIQ4 | c.540C>T p.F180= | Silent (SNP) | VAF 49/309 reads (16%) | catalogued as rs867617630, COSV61619254; called by muse, mutect2, varscan2
- MAP3K1 | c.1371A>T p.T457= | Silent (SNP) | VAF 38/69 reads (55%) | catalogued as COSV101266734; called by muse, mutect2, varscan2
- MKRN3 | c.546C>T p.A182= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as rs200863828, COSV100091116; called by muse, mutect2, varscan2
- MYO18B | c.3444C>G p.G1148= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV100123584; called by muse, varscan2
- MYT1L | c.2868G>T p.G956= | Silent (SNP) | VAF 34/91 reads (37%) | catalogued as COSV67701031; called by muse, mutect2, varscan2
- PDZD2 | c.4776G>T p.S1592= | Silent (SNP) | VAF 50/157 reads (32%) | catalogued as COSV56870634, COSV99224918; called by muse, mutect2, varscan2
- RREB1 | c.2889G>A p.A963= | Silent (SNP) | VAF 13/17 reads (76%) | catalogued as COSV100619340; called by muse, mutect2, varscan2
- SAP130 | c.222C>T p.V74= | Silent (SNP) | VAF 32/85 reads (38%) | catalogued as COSV99384660; called by muse, mutect2, varscan2
- SELPLG | c.1170G>T p.P390= | Silent (SNP) | VAF 20/28 reads (71%) | catalogued as COSV99947402; called by muse, varscan2
- SORCS1 | c.2976G>A p.P992= | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as rs781562067, COSV53840740, COSV99546222; called by muse, mutect2, varscan2
- TCFL5 | c.1173G>A p.Q391= | Silent (SNP) | VAF 139/180 reads (77%) | catalogued as COSV53895945, COSV99415839; called by muse, mutect2, varscan2
- TKTL2 | c.1266G>C p.G422= | Silent (SNP) | VAF 38/60 reads (63%) | catalogued as COSV99761373; called by muse, mutect2, varscan2
- WSCD2 | c.1176C>T p.S392= | Silent (SNP) | VAF 152/210 reads (72%) | catalogued as rs368092771, COSV54585703; called by muse, mutect2, varscan2
- ZNF83 | c.471C>T p.V157= | Silent (SNP) | VAF 28/52 reads (54%) | catalogued as COSV99991356; called by muse, mutect2, varscan2
- ARHGAP42 | c.*3526G>T | 3'UTR (SNP) | VAF 34/90 reads (38%) | catalogued as COSV100082406; called by muse, mutect2, varscan2
- SUN1 | c.659-243T>C | Intron (SNP) | VAF 59/105 reads (56%) | catalogued as rs759921230; called by muse, mutect2, varscan2
